Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAED, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAED-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver ,LN

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organ: Liver (18.0 x 9.5 x 7.0 cm, 617.0 gm)

Gallbladder (7.3 cm in length, 3.1 cm in diameter, 0.3 cm in thickness)

[Liver]

Lesion: A hepatic mass

Size: 8.5 x 7.8 x 10.5 cm

Cut surface: Well demarcated, nodular lesion with area of necrosis

Gross type: Expansile

Extent: Confined to the hepatic parenchyma

Serosal surface: Bulging but smooth

Resection margin: Not involved, grossly (safety margin: 0.4 cm)

Remaining parenchyme: Non-cirrhotic

[Gallbladder]

Serosal surface: Yellowish pink and smooth

Mucosal surface: Dark green and velvety

Stone: No stone

Representative sections submitted

Gross photo: Present

Blocks

T1-4, TB, mass of liver x 5

RM, resection margin x 1

L, NB, nontumorous liver parenchyme x 2

LN, fatty tissue x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation III

The major differentiation III

Histologic type: Trabecular

Fatty change: No

Fibrous capsule formation: Yes

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
JW 5/20/14

[page 2 of 2]
Capsular infiltration: Yes
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Vascular invasion: Yes
Bile duct invasion: No
Remaining liver parenchyme: Periportal fibrosis (stage 2) with mild steatosis

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma,Periportal fibrosis, mild steatosis
T56000, P10, M81703, Periportal fibrosis, mild steatosis
gallbladder,ectomy,autolysis
T57000, P10, M54001

DIAGNOSIS:

Liver, partial hepatectomy:
Hepatocellular carcinoma, moderately differentiated
Periportal fibrosis with mild steatosis

Galllbladder, cholecystectomy:
Autolysis

Suggestion :

Source: NCI Genomic Data Commons file d715da19-d8e4-4f32-98d2-618d54b51d67 (TCGA-DD-AAED.EEA08FBB-E73F-4DC8-91D8-DE3FBDFCA0F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).